Gene-level copy-number profile of tumor specimen C3N-01620-03 from CPTAC case C3N-01620, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 56.9 years (20,774 days).
Specimen C3N-01620-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 30fa92a0-31cd-4e2c-a622-0997e1454a60.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01620-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/b904ba26-cddf-4eeb-8f70-227bc2d60f0a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 154; copy number 1: 13,054; copy number 2: 40,877; copy number 3: 4,048; copy number 4: 741; copy number 6: 7; copy number 7: 4; copy number 8: 19; copy number 10: 5.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:116,489,364–116,515,619, 1 gene: AC106892.1.
- chr4:117,834,145–117,869,960, 1 gene: LINC02264.
- chr9:9,090,898–9,442,380, 2 genes (within-gene range 0–2): RPS26P3, RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:60,914,407–61,662,690, 16 genes, copy number 6–10: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:90,251,204–92,336,496, 19 genes, copy number 8: DISC1FP1, TUBAP2, MIR4490, AP002782.1, MIR1261, AP001002.3, AP001002.1, AP001002.2, OSBPL9P2, OSBPL9P3, LINC02748, AP003485.2, AP003485.1, AP002791.1, LINC02756, TUBB4BP4, AP002799.1, RPL7AP57, NDUFB11P1.

Autosomal genes at a single copy (total copy number 1): 10,353. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
